FM case AD706 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Anus and anal canal.
https://portal.gdc.cancer.gov/cases/6918cb1a-07cd-4c1e-94f2-59fb93e54e51

Female, 61.7 years: Basaloid carcinoma (ICD-O-3 8123/3) of the anus; metastasis biopsied or resected from the rectum. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
